CCDI case PBCECS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/81300726-acde-4694-b051-c82353a39042

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 4.6 years (1,666 days).

Biospecimens (3 samples)
- Sample 0DPZTD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPZTL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DPZUD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
